Somatic mutation profile of tumor specimen ALCH-B3DU-TTP1-A (aliquot ALCH-B3DU-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3DU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Invasive mucinous adenocarcinoma; Age at diagnosis: 75.1 years (27,423 days).
Specimen ALCH-B3DU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23cf8fdc-ed74-4c68-a713-9b0f6af4978e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3DU-NB1-A (Blood Derived Normal), aliquot ALCH-B3DU-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44dd0419-fa43-4e55-9913-547492813117

The open-access MAF lists 213 somatic variants for this specimen: 145 protein-altering or splice-affecting, 45 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 45, Intron 15, Nonsense Mutation 13, Splice Site 6, 3'UTR 3, Frame Shift Ins 2, 5'UTR 2, Translation Start Site 2, Frame Shift Del 2, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 42/450 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- PIK3CA | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs863225060, COSV55878075, COSV55925758; ClinVar: likely pathogenic; called by muse, varscan2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 11/148 reads (7%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ACTA1 | c.550G>T p.G184C | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV64203101; called by muse, mutect2
- ADAMTS9 | c.5584G>T p.D1862Y | Missense Mutation (SNP) | VAF 24/406 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758536387; called by muse, mutect2
- AP3B2 | c.1420C>G p.L474V | Missense Mutation (SNP) | VAF 23/404 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV55615478; called by muse, mutect2
- CD6 | c.1900C>A p.P634T | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs1162571892, COSV57840447; called by muse, mutect2
- CNTN1 | c.2660C>T p.A887V | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV61645895; called by muse, mutect2, varscan2
- DCPS | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 26/401 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as rs755203724; called by muse, mutect2
- DNAI3 | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 40/408 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV54004031; called by muse, mutect2
- DPP6 | c.1987C>G p.R663G (on ENST00000377770 / NM_001364500.2; = p.R601G on NM_001936.5) | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59600522; called by muse, varscan2
- EDIL3 | c.1038G>T p.M346I | Missense Mutation (SNP) | VAF 30/406 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.055); catalogued as rs1349653727; called by muse, mutect2
- EGR3 | c.1067T>G p.L356R | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1392362378; called by muse, mutect2
- EPB41L3 | c.649A>T p.R217W | Missense Mutation (SNP) | VAF 34/400 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59444262; called by muse, mutect2
- F9 | c.794C>A p.A265D | Missense Mutation (SNP) | VAF 41/292 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM035523; called by muse, mutect2, varscan2
- FAT1 | c.8537A>G p.Y2846C | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs775685435; called by muse, mutect2, varscan2
- GABRG1 | c.1274G>C p.G425A | Missense Mutation (SNP) | VAF 50/658 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.44); catalogued as COSV54952975; called by muse, mutect2
- GALNT15 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs1370798877; called by muse, mutect2
- H2BC21 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 42/556 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.022); catalogued as rs1173782059; called by muse, mutect2
- HARS1 | c.300+1G>T p.X100_splice | Splice Site (SNP) | VAF 11/123 reads (9%) | catalogued as COSV56909689; called by muse, mutect2
- HYDIN | c.7532G>T p.R2511L | Missense Mutation (SNP) | VAF 23/270 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59273498; called by muse, mutect2
- KCNH8 | c.2248G>T p.G750C | Missense Mutation (SNP) | VAF 29/415 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776698986; called by muse, mutect2
- KIF1A | c.1635C>A p.S545R | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV57496936; called by muse, mutect2, varscan2
- KRT13 | c.745G>T p.E249* | Nonsense Mutation (SNP) | VAF 14/196 reads (7%) | catalogued as COSV55839031; called by muse, mutect2
- KYNU | c.987C>A p.F329L | Missense Mutation (SNP) | VAF 40/641 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.201); catalogued as COSV51579794; called by muse, mutect2
- LILRA5 | c.653G>C p.R218P | Missense Mutation (SNP) | VAF 22/347 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV56645176; called by muse, mutect2
- LILRB4 | c.1044+8C>A | Splice Region (SNP) | VAF 16/135 reads (12%) | catalogued as rs767737563; called by muse, mutect2, varscan2
- LOXHD1 | c.1838C>A p.T613N | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as COSV59661073; called by muse, mutect2
- LRTM1 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 44/528 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs372086680, COSV55520410; called by muse, mutect2
- PABPC4L | c.1104G>T p.Q368H | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV69929153; called by muse, mutect2
- PCDHA12 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 36/400 reads (9%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.253); catalogued as COSV56487703; called by muse, mutect2
- PCDHB10 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 32/358 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); catalogued as rs781947513, COSV53377622; called by muse, mutect2, varscan2
- PCDHGA1 | c.2095G>T p.A699S | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.1); catalogued as COSV65296784; called by muse, mutect2
- PCDHGA7 | c.1438G>T p.D480Y | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV54016517; called by muse, mutect2
- PHF13 | c.598A>G p.I200V | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1249855112; called by muse, mutect2, varscan2
- PJA2 | c.640G>C p.G214R | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.653); catalogued as rs753449132; called by muse, mutect2
- PNLIP | c.54A>T p.E18D | Missense Mutation (SNP) | VAF 43/535 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV65040728; called by muse, mutect2
- PPP1R3A | c.1444T>A p.L482M | Missense Mutation (SNP) | VAF 14/223 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99492282; called by muse, mutect2
- PXDNL | c.4222C>T p.R1408C | Missense Mutation (SNP) | VAF 26/386 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.849); catalogued as rs537952252, COSV62487421; called by muse, mutect2
- SAG | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 26/508 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.382); catalogued as COSV68592238; called by muse, mutect2
- SEC63 | c.1303G>T p.V435F | Missense Mutation (SNP) | VAF 40/438 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs377599674; called by muse, mutect2
- SLITRK3 | c.200C>A p.T67K | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.353); catalogued as rs1253214209; called by muse, mutect2, varscan2
- TTN | c.16834G>T p.D5612Y (on ENST00000591111; = p.D4685Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | PolyPhen probably damaging (0.964); catalogued as COSV59866317; called by muse, mutect2
- USP34 | c.2483A>G p.H828R | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1244161383; called by muse, mutect2
- VWA5B2 | c.2750G>A p.R917Q | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs149481274; called by muse, mutect2
- WDR62 | c.1510G>T p.G504C | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs972775756; called by muse, mutect2
- XKR9 | c.994G>T p.G332* | Nonsense Mutation (SNP) | VAF 16/218 reads (7%) | catalogued as COSV101281891, COSV101281982; called by muse, mutect2
- XKR9 | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68772783; called by muse, mutect2
- ZNF384 | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100158243; called by muse, mutect2
- ABCA13 | c.14578G>A p.G4860R | Missense Mutation (SNP) | VAF 23/307 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADCY5 | c.1249G>T p.A417S | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.1); called by muse, mutect2
- AKR1E2 | c.130A>T p.R44W | Missense Mutation (SNP) | VAF 27/433 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2
- ANGPTL2 | c.1351G>C p.V451L | Missense Mutation (SNP) | VAF 30/401 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- AP1S1 | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 32/322 reads (10%) | called by muse, mutect2
- ARHGEF3 | c.331T>G p.C111G | Missense Mutation (SNP) | VAF 32/399 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- ATXN1 | c.470G>C p.S157T | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.176); called by muse, mutect2
- BRD1 | c.1024C>T p.H342Y | Missense Mutation (SNP) | VAF 15/201 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- C10orf90 | c.1628C>A p.S543* | Nonsense Mutation (SNP) | VAF 17/241 reads (7%) | called by muse, mutect2
- C20orf194 | c.1357-2A>T p.X453_splice | Splice Site (SNP) | VAF 16/142 reads (11%) | called by muse, mutect2, varscan2
- C22orf15 | c.244A>G p.I82V | Missense Mutation (SNP) | VAF 13/234 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0.007); called by muse, mutect2
- CACNA2D4 | c.262C>A p.L88M | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); called by muse, mutect2
- CCDC168 | c.7823A>G p.N2608S | Missense Mutation (SNP) | VAF 11/202 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.019); called by muse, mutect2
- CEP128 | c.2083A>T p.R695W | Missense Mutation (SNP) | VAF 22/405 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- CEP78 | c.1556G>T p.G519V (on ENST00000424347 / NM_001349840.2; = p.G520V on NM_032171.3) | Missense Mutation (SNP) | VAF 28/368 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- CNTN5 | c.668C>A p.S223* | Nonsense Mutation (SNP) | VAF 19/182 reads (10%) | called by muse, mutect2, varscan2
- COL1A2 | c.1088C>A p.P363H | Missense Mutation (SNP) | VAF 27/770 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- CSMD2 | c.6014-2A>G p.X2005_splice | Splice Site (SNP) | VAF 11/144 reads (8%) | called by muse, mutect2
- DEFB4B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- DENND1A | c.2185G>T p.A729S | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH5 | c.572A>T p.D191V | Missense Mutation (SNP) | VAF 56/611 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.017); called by muse, mutect2
- DOCK1 | c.5012C>G p.P1671R | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.758); called by muse, mutect2
- DYRK4 | c.243C>A p.S81R | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2
- DZIP3 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.373); called by muse, mutect2
- EDIL3 | c.1039G>T p.D347Y | Missense Mutation (SNP) | VAF 28/397 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- EIF5A2 | c.56C>A p.P19H | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EMILIN2 | c.366del p.D124Tfs*3 | Frame Shift Del (DEL) | VAF 15/118 reads (13%) | called by mutect2, pindel, varscan2
- EPHA7 | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ERICH3 | c.1824C>G p.D608E | Missense Mutation (SNP) | VAF 34/431 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ESRP2 | c.809A>T p.D270V (on ENST00000565858 / NM_001365264.1; = p.D260V on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/249 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- EXPH5 | c.3451G>T p.E1151* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- FPR2 | c.663T>A p.Y221* | Nonsense Mutation (SNP) | VAF 32/434 reads (7%) | called by muse, mutect2
- FRY | c.6286G>T p.D2096Y | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- GRHL2 | c.971A>G p.Q324R | Missense Mutation (SNP) | VAF 54/563 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRM7 | c.1793C>A p.A598E | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- IL4R | c.2264C>T p.P755L | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- INO80D | c.975G>A p.W325* | Nonsense Mutation (SNP) | VAF 28/323 reads (9%) | called by muse, mutect2
- ITGAD | c.927G>T p.Q309H | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITGB2 | c.1748G>C p.C583S (on ENST00000302347; = p.C559S on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- ITGBL1 | c.1004G>T p.C335F | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KANK4 | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 7/118 reads (6%) | called by muse, mutect2
- KCNA2 | c.391G>C p.G131R | Missense Mutation (SNP) | VAF 34/340 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KEL | c.2125C>A p.P709T | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.598); called by muse, mutect2
- KLK8 | c.551G>T p.C184F | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KPRP | c.1295T>C p.L432S | Missense Mutation (SNP) | VAF 18/350 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.985); called by muse, mutect2
- KRTAP4-5 | c.382T>G p.S128A | Missense Mutation (SNP) | VAF 33/332 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- LPAR1 | c.633del p.I212Ffs*5 | Frame Shift Del (DEL) | VAF 32/263 reads (12%) | called by mutect2, varscan2
- LTBP2 | c.3915C>A p.D1305E | Missense Mutation (SNP) | VAF 50/501 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- MEGF10 | c.911G>C p.G304A | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2
- MIB2 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by muse, varscan2
- MYH14 | c.5520G>T p.L1840F | Missense Mutation (SNP) | VAF 12/173 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2
- MYO1H | c.718C>G p.R240G | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.577); called by muse, mutect2
- MYO7A | c.5403G>T p.E1801D | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MYOZ3 | c.223G>T p.A75S | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- NBPF25P | n.1498-1G>T | Splice Site (SNP) | VAF 30/1055 reads (3%) | called by muse, mutect2
- NEO1 | c.3739C>T p.Q1247* | Nonsense Mutation (SNP) | VAF 19/192 reads (10%) | called by muse, mutect2
- NLRP9 | c.358C>A p.P120T | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2
- NOX4 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 19/152 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- NPHS2 | c.474C>A p.C158* | Nonsense Mutation (SNP) | VAF 40/500 reads (8%) | called by muse, mutect2
- NUFIP1 | c.1198G>T p.A400S | Missense Mutation (SNP) | VAF 25/386 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- OR2G3 | c.567T>A p.C189* | Nonsense Mutation (SNP) | VAF 11/168 reads (7%) | called by muse, mutect2
- OR8B12 | c.473A>T p.H158L | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- OVCH2 | c.1543C>A p.L515M | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- PDX1 | c.95C>G p.P32R | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PEAR1 | c.2713+1G>T p.X905_splice | Splice Site (SNP) | VAF 9/140 reads (6%) | called by muse, mutect2
- PEG3 | c.3951C>A p.H1317Q | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); called by muse, mutect2
- PLEKHA7 | c.2777C>G p.P926R | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PLOD2 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.77); called by muse, mutect2
- POTEE | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 39/611 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.918); called by muse, mutect2
- PSCA | c.26-1G>T p.X9_splice | Splice Site (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2
- RBBP6 | c.4366C>T p.H1456Y | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.388); called by muse, mutect2
- RGPD3 | c.4952C>A p.T1651N | Missense Mutation (SNP) | VAF 38/302 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ROS1 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- RP1L1 | c.6351G>T p.E2117D | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); called by muse, mutect2
- SAG | c.673C>A p.P225T | Missense Mutation (SNP) | VAF 28/515 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2
- SERPINA10 | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.554); called by muse, mutect2
- SEZ6L | c.1093A>T p.N365Y | Missense Mutation (SNP) | VAF 19/191 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHMT1 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 32/330 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- SLC22A11 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2
- SLC46A3 | c.966G>T p.M322I | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SLC5A12 | c.144G>T p.M48I | Missense Mutation (SNP) | VAF 32/488 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2
- SNAP25 | c.589C>A p.Q197K | Missense Mutation (SNP) | VAF 26/440 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2
- STAT5B | c.2289G>C p.M763I | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.771); called by muse, mutect2
- STK38 | c.1115G>T p.G372V | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2
- SULT1A1 | c.873C>G p.F291L | Missense Mutation (SNP) | VAF 16/488 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.592); called by muse, mutect2
- SVEP1 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.223); called by muse, mutect2
- SYT9 | c.943C>A p.R315S | Missense Mutation (SNP) | VAF 29/472 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); called by muse, mutect2
- TAS1R3 | c.389dup p.N130Kfs*41 | Frame Shift Ins (INS) | VAF 29/236 reads (12%) | called by mutect2, pindel, varscan2
- THY1 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 31/374 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2
- TMEM132C | c.2989dup p.I997Nfs*83 | Frame Shift Ins (INS) | VAF 18/151 reads (12%) | called by mutect2, pindel, varscan2
- TSHZ2 | c.1376A>T p.E459V | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.163); called by muse, mutect2
- TTLL5 | c.434A>T p.H145L | Missense Mutation (SNP) | VAF 31/291 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- VPS39 | c.2007G>C p.E669D (on ENST00000348544 / NM_001301138.2; = p.E658D on NM_015289.5) | Missense Mutation (SNP) | VAF 9/251 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.041); called by muse, mutect2
- WFDC3 | c.28A>G p.K10E | Missense Mutation (SNP) | VAF 19/274 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.142); called by muse, mutect2
- ZNF264 | c.1505A>G p.K502R | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.043); called by muse, mutect2
- ZNF99 | c.1023C>A p.Y341* | Nonsense Mutation (SNP) | VAF 35/502 reads (7%) | called by muse, mutect2
- ADAMTS20 | c.4524G>T p.V1508= | Silent (SNP) | VAF 19/275 reads (7%) | called by muse, mutect2
- BCO2 | c.1116G>A p.L372= | Silent (SNP) | VAF 13/326 reads (4%) | called by muse, mutect2
- CDH11 | c.225C>T p.G75= | Silent (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- CLTCL1 | c.2682G>A p.L894= | Silent (SNP) | VAF 24/246 reads (10%) | catalogued as rs782537062; called by muse, mutect2, varscan2
- COL4A3 | c.1764G>C p.L588= | Silent (SNP) | VAF 16/320 reads (5%) | catalogued as COSV67421762; called by muse, mutect2
- DPP6 | c.1986C>A p.G662= (on ENST00000377770 / NM_001364500.2; = p.G600= on NM_001936.5) | Silent (SNP) | VAF 15/98 reads (15%) | called by muse, varscan2
- DSCAML1 | c.2109G>T p.V703= (on ENST00000321322; = p.V643= on NM_020693.4) | Silent (SNP) | VAF 27/324 reads (8%) | called by muse, mutect2
- ELANE | c.270G>A p.S90= | Silent (SNP) | VAF 6/136 reads (4%) | catalogued as rs1163809368; called by muse, mutect2
- FLG | c.3363G>T p.V1121= | Silent (SNP) | VAF 32/443 reads (7%) | called by muse, mutect2
- FUT5 | c.177C>G p.P59= | Silent (SNP) | VAF 8/117 reads (7%) | catalogued as COSV99399052; called by muse, mutect2
- FZD1 | c.438G>T p.A146= | Silent (SNP) | VAF 25/233 reads (11%) | catalogued as rs762347513, COSV55308681; called by muse, mutect2, varscan2
- HPR | c.771C>T p.G257= | Silent (SNP) | VAF 27/278 reads (10%) | called by muse, mutect2
- IGHV3-16 | c.102G>T p.G34= | Silent (SNP) | VAF 24/294 reads (8%) | called by muse, mutect2
- IL21 | c.63G>T p.G21= | Silent (SNP) | VAF 30/428 reads (7%) | called by muse, mutect2
- ITGB2 | c.492C>A p.G164= | Silent (SNP) | VAF 38/264 reads (14%) | called by muse, mutect2, varscan2
- KIAA2012 | c.912C>A p.A304= | Silent (SNP) | VAF 16/279 reads (6%) | called by muse, mutect2
- LOXHD1 | c.1839C>A p.T613= | Silent (SNP) | VAF 22/288 reads (8%) | called by muse, mutect2
- LRP8 | c.294C>T p.C98= | Silent (SNP) | VAF 20/262 reads (8%) | called by muse, mutect2
- MANEAL | c.60C>T p.F20= | Silent (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2, varscan2
- MTG1 | c.543G>T p.G181= | Silent (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- MTOR | c.1467G>T p.L489= | Silent (SNP) | VAF 15/300 reads (5%) | called by muse, mutect2
- NFIL3 | c.954G>T p.V318= | Silent (SNP) | VAF 27/403 reads (7%) | called by muse, mutect2
- OAZ3 | c.261C>T p.S87= | Silent (SNP) | VAF 12/306 reads (4%) | called by muse, mutect2
- OR10V1 | c.96G>C p.L32= | Silent (SNP) | VAF 16/314 reads (5%) | called by muse, mutect2
- OR51I2 | c.921T>C p.F307= | Silent (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- OTOF | c.3159C>A p.A1053= (on ENST00000272371 / NM_194248.3; = p.A306= on NM_004802.4) | Silent (SNP) | VAF 20/258 reads (8%) | called by muse, mutect2
- P2RY2 | c.657G>T p.V219= | Silent (SNP) | VAF 21/211 reads (10%) | called by muse, mutect2
- PCDH8 | c.1839G>C p.A613= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as rs763294279; called by muse, mutect2
- PDZRN3 | c.2415C>A p.S805= | Silent (SNP) | VAF 17/246 reads (7%) | called by muse, mutect2
- PLXNB3 | c.5487C>T p.D1829= | Silent (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2, varscan2
- POM121L12 | c.735C>A p.L245= | Silent (SNP) | VAF 16/142 reads (11%) | catalogued as COSV101374895, COSV68693088; called by muse, mutect2
- PRKCG | c.1377C>T p.F459= | Silent (SNP) | VAF 36/422 reads (9%) | catalogued as COSV99668738; called by muse, mutect2
- PTPRQ | c.6574C>A p.R2192= (on ENST00000616559; = p.R2159= on NM_001145026.2) | Silent (SNP) | VAF 20/339 reads (6%) | catalogued as CM136600, COSV57037727; called by muse, mutect2
- PXDN | c.2118C>T p.N706= | Silent (SNP) | VAF 33/339 reads (10%) | catalogued as rs752768393, COSV53227154; called by muse, mutect2, varscan2
- RBSN | c.2175C>T p.D725= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as rs1429514550; called by muse, mutect2, varscan2
- RTL1 | c.2334G>T p.L778= | Silent (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2
- SLC6A13 | c.1053C>A p.A351= | Silent (SNP) | VAF 32/283 reads (11%) | called by muse, mutect2, varscan2
- STARD3 | c.102G>T p.S34= | Silent (SNP) | VAF 38/448 reads (8%) | catalogued as COSV60419996; called by muse, mutect2
- SVEP1 | c.4341T>C p.S1447= | Silent (SNP) | VAF 37/462 reads (8%) | called by muse, mutect2
- TSPAN19 | c.231A>T p.G77= | Silent (SNP) | VAF 13/206 reads (6%) | called by muse, mutect2
- TUBGCP6 | c.162T>G p.T54= | Silent (SNP) | VAF 18/196 reads (9%) | called by muse, mutect2, varscan2
- WSCD2 | c.693A>G p.A231= | Silent (SNP) | VAF 19/140 reads (14%) | called by muse, mutect2
- XIRP1 | c.1266G>T p.L422= | Silent (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2, varscan2
- ZFAT | c.2076G>T p.G692= | Silent (SNP) | VAF 25/251 reads (10%) | called by muse, mutect2, varscan2
- ZFYVE26 | c.984G>C p.L328= | Silent (SNP) | VAF 26/524 reads (5%) | catalogued as COSV61331969; called by muse, mutect2
- A1BG | c.*58T>A | 3'UTR (SNP) | VAF 24/290 reads (8%) | called by muse, mutect2
- ARHGEF10 | c.754+108G>A | Intron (SNP) | VAF 20/288 reads (7%) | called by muse, mutect2
- CAD | c.6378+17C>G | Intron (SNP) | VAF 15/246 reads (6%) | called by muse, mutect2
- CEP350 | c.4793-717G>T | Intron (SNP) | VAF 41/285 reads (14%) | called by muse, mutect2, varscan2
- COMMD9 | chr11:36271700 G>C | 3'Flank (SNP) | VAF 22/290 reads (8%) | called by muse, mutect2
- CPNE7 | c.1764+252G>T | Intron (SNP) | VAF 16/208 reads (8%) | called by muse, mutect2
- DIO3 | chr14:101557569 G>T | 5'Flank (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- FAM169B | n.692C>A | RNA (SNP) | VAF 28/354 reads (8%) | called by muse, mutect2
- HELB | c.2156-36A>G | Intron (SNP) | VAF 11/124 reads (9%) | called by muse, mutect2, varscan2
- ITSN1 | c.346+156G>C | Intron (SNP) | VAF 15/182 reads (8%) | called by muse, mutect2
- LGALS12 | c.*5G>C | 3'UTR (SNP) | VAF 22/316 reads (7%) | called by muse, mutect2
- NEIL3 | c.-25G>C | 5'UTR (SNP) | VAF 10/239 reads (4%) | called by muse, mutect2
- NTNG1 | c.1087+10929C>A | Intron (SNP) | VAF 11/181 reads (6%) | called by muse, mutect2
- PDAP1 | c.*25G>T | 3'UTR (SNP) | VAF 26/382 reads (7%) | called by muse, mutect2
- PDE10A | c.106+91639C>T | Intron (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- PIP5K1B | c.69+1478G>A | Intron (SNP) | VAF 54/552 reads (10%) | called by muse, mutect2
- PRSS1 | c.200+366C>G | Intron (SNP) | VAF 12/196 reads (6%) | called by muse, mutect2
- PTPRK | c.100+1177_100+1178dup | Intron (INS) | VAF 36/358 reads (10%) | called by mutect2, pindel
- ROBO2 | c.1683-489G>A | Intron (SNP) | VAF 6/141 reads (4%) | called by muse, mutect2
- SATB2 | c.347-15964C>A | Intron (SNP) | VAF 18/200 reads (9%) | called by muse, mutect2
- SEL1L2 | c.387-1184A>C | Intron (SNP) | VAF 13/165 reads (8%) | called by muse, mutect2
- SGIP1 | c.1315+1794G>T | Intron (SNP) | VAF 28/347 reads (8%) | called by muse, mutect2
- TMEM151A | c.-42G>T | 5'UTR (SNP) | VAF 10/94 reads (11%) | called by muse, varscan2
